Surgical pathology report (de-identified scan), TCGA case TCGA-66-2763, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2763-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left upper lobe, among others

Clinical diagnosis and question

Space-occupying lesion of unclear pathogenesis left upper lobe, with pleural contact.

REPORT ON FINDINGS**Macroscopy**

- 1.) Inflated, fixed upper lobe of left lung measuring 24 x 14 x 7 cm, central bronchus resection plane located 0.8 cm proximal to the bifurcation of the lingular bronchus. A 4.5 cm long staple suture line runs in a dorsocaudal direction from the hilus. At the hilus are four lesioned grayish-black nodes between 0.8 and 1.4 cm. Lateral pleural over segment 2 shows an unclearly demarcated 3 cm area of whitish discoloration characterized by a depression-like retraction, under which is a moderately solid, predominantly pale brownish and partly patchy grayish-black tumor, max. 5.5 cm in size, with a relatively clear and somewhat arcuate demarcation, extending to the pleura in the region of the retraction. Truncation or opening of peripheral branches of B2, B1 and B3 in the tumor. Lateral pleural region at the junction of S3/S4 shows an unclearly demarcated 0.4 cm area of induration. Rest of parenchyma shows rarefaction in apical region of segment 1 with lacunae or lacuna systems up to 0.6 cm in size, otherwise inconspicuous.
- 2.) Parietal pleura: membranous tissue measuring 10.5 x 8.5 cm and up to 0.1 cm thick with partly smooth, partly rough surface.
- 3) Interlobar LN (item 11) left: three lesioned grayish-black nodes or node parts, 0.3 and 1.1 cm in size.
- 4) Hilar LN (item 10) left: two lesioned grayish-black nodes or node parts, 0.4 and 1.3 cm in size, partly with some surrounding tissue.
- 5) Subcarinal LN (item 7): 1 cm lesioned grayish-black node or node part.
- 6) Paraaortic LN (item 6) left: combined 1.5 cm quantity of partly grayish-red, partly blackish specimens between 0.1 and 0.8 cm.
- 7) Subaortic LN (aortopulmonary window) (item 5) left: 2 cm lesioned grayish-black nodes with some surrounding tissue.
- 8.) Low paratracheal LN (item 4) left: 2.2 cm lesioned grayish-brown node with some surrounding tissue.

Examined:

- 1.) 2 sections of tumor with remaining parenchyma, 3 sections with pleura, indurated area (halved), 2 sections of apical S1, central bronchus resection plane, resection margins of vessels, hilar nodes,
- 2.) All material (lamellated),
- 3.) - 8.) All material (in 7. + 8. preparations lamellated),
- 15 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Intermediate to peripheral manifest bronchopulmonary, histologically poorly differentiated, partly gigantocellular and polymorphocellular squamous cell carcinoma of the upper lobe of the left lung. TNM classification according to this picture pT2 pN0 V1 R0, stage IB. C 34.1; M 8070/3.

Secondary diagnosis/diagnoses:

Small tumor necroses and tumor-related inflammation. Active, partly resorptive inflammation of the lung parenchyma surrounding the tumor with inclusion of numerous macrophages. Circumscribed subpleural alveolar and interstitial organizing and remodeling zone of the lung parenchyma with inclusion of immature or atypical squamous cell metaplasia also involving the bronchioles (S3 /4). Apical emphysematous stromal remodeling with formation of small subpleural cysts. Slight anthracotic pigment deposits in the lung parenchyma and moderately marked deposits in the lymph nodes. Chronic parietal pleuritis with fibrosis of varying degrees (sample 2.)).

Remark/addendum:

This is probably a primarily peripheral carcinoma of the lung which, after central growth, has infiltrated intermediate or subsegmental bronchi of segments 1 – 3 there, because there is tumor invasion of the overlying visceral pleura, where there is also marked fibrosis. The main tumor mass is located in segment 2. The fibrosing lesion of the lung parenchyma in the boundary region of segments S3/4, which includes atypical squamous cell nests, could be the initial stage of a second bronchopulmonary carcinoma focus, because the histological picture is not typical of a satellite nodule. But ultimately, the differential diagnosis of an atypical squamous cell metaplasia in the context of a circumscribed fibrosing process initiated by inflammation cannot be made with a sufficient degree of reliability.

Source: NCI Genomic Data Commons file dcf91548-5e3a-4209-8efd-1613b251fe0e (TCGA-66-2763.109E31CB-1414-4D8C-89DA-C3B3ECCF20A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).